Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4714, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4714-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: RENAL VEIN MARGIN, BIOPSY –
PORTION OF VEIN, NO TUMOR SEEN.

PART 2: KIDNEY, RIGHT, RADICAL NEPHRECTOMY –

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, 5.0 CM IN GREATEST DIMENSION, FUHRMAN NUCLEAR GRADE III/IV.
- B. CARCINOMA INVADIES THE RENAL VEIN.
- C. CARCINOMA FOCALLY INVOLVES RENAL SINUS FAT.
- D. ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- E. NON-NEOPLASTIC KIDNEY SHOWS FOCAL GLOBAL GLOMERULOSCLEROSIS IN A BACKGROUND OF MODERATELY SEVERE HYPERTENSIVE VASCULAR DISEASE.
- F. ADRENAL GLAND WITH METASTATIC (NON-CONTIGUOUS) RENAL CELL CARCINOMA.
- G. TNM STAGE: pT3b Nx M1 (see part 3 and comment).

PART 3: LYMPH NODE, "HYALINE" (PRESUMABLY, HILAR), EXCISION –

- A. NODULAR DEPOSIT OF RENAL CELL CARCINOMA.
- B. RESIDUAL LYMPHOID TISSUE IS NOT IDENTIFIED (See comment).

COMMENT:

Part 3 is composed of a nodule of renal cell carcinoma with surrounding fibromuscular and adipose tissue. There are no lymphocytes and no suggestion of lymph node architecture. Lymph node involvement cannot therefore be confirmed histologically and this nodule is favored to represent either a soft tissue deposit or an intravascular nodule of tumor. The deposit in the adrenal gland is separate from the main tumor mass and is therefore considered a metastatic deposit. The pathologic stage is therefore rendered as pT3b Nx M1.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY KIDNEY TUMORS

SPECIMEN TYPE: Radical nephrectomy

LATERALITY: Right

TUMOR SITE: Upper pole

FOCALITY: Middle

TUMOR SIZE: Unifocal

Greatest dimension: 5 cm

Additional dimensions: 4.5 x 4.0 cm

MACROSCOPIC EXTENT OF TUMOR: Tumor extension into perinephric tissues

HISTOLOGIC TYPE: Clear cell (conventional) renal carcinoma

HISTOLOGIC GRADE (Fuhrman Nuclear Grade): G3

PATHOLOGIC STAGING (pTNM): pT3b

pNX

Number of regional lymph nodes examined: 0

pM1

Site(s): adrenal

MARGINS: Margins uninvolved by invasive carcinoma

ADRENAL GLAND: Metastasis (M1)

VENOUS (LARGE VESSEL) INVASION (V): Present

LYMPHATIC (SMALL VESSEL) INVASION (L): Indeterminate

Source: NCI Genomic Data Commons file 08ce4ca8-3e2c-4600-aeb7-4dc95f36ffd6 (TCGA-B0-4714.DFEF8BB2-0697-4EDE-8ED3-28DA9F7B201F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).